Somatic mutation profile of tumor specimen TCGA-A6-A566-01A (aliquot TCGA-A6-A566-01A-11D-A28G-10) from TCGA case TCGA-A6-A566, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 55.3 years (20,181 days).
Specimen TCGA-A6-A566-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06eb9c52-50ba-4ea7-8b7e-037803a84c91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-A566-10A (Blood Derived Normal), aliquot TCGA-A6-A566-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7665285a-8991-4879-9c7e-372d07516f39

The open-access MAF lists 210 somatic variants for this specimen: 141 protein-altering or splice-affecting, 53 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 53, Nonsense Mutation 9, Frame Shift Del 7, 3'UTR 5, Splice Region 4, Intron 4, Splice Site 3, Frame Shift Ins 3, 5'Flank 3, 3'Flank 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.6037+1G>A p.X2013_splice | Splice Site (SNP) | VAF 13/57 reads (23%) | catalogued as rs1064796636, CS042165, COSV100355297; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 29/78 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.6819+1G>A p.X2273_splice (on ENST00000358273 / NM_001042492.3; = p.X2252_splice on NM_000267.3) | Splice Site (SNP) | VAF 13/102 reads (13%) | catalogued as rs1555534964, CS000887, COSV62201315, COSV62218236; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 30/143 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as rs1064793732, CM126690, COSV55881636, COSV55977337; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASS | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs370266183, COSV100741592, COSV62789109; called by muse, mutect2, varscan2
- ACVR2A | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 34/129 reads (26%) | catalogued as COSV54018614; called by muse, mutect2, varscan2
- ADAMTS18 | c.2468G>A p.R823H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs189744529, COSV51401748; called by muse, mutect2, varscan2
- ADAMTS20 | c.4594C>A p.Q1532K | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV67132414; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4175C>T p.P1392L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs368567865; called by muse, mutect2, varscan2
- ANKRD30B | c.2560G>T p.D854Y | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.557); catalogued as rs1291981507, COSV57703722; called by muse, mutect2, varscan2
- ARHGEF28 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756328784, COSV55265469; called by muse, mutect2, varscan2
- ARSA | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as rs900681963, COSV53350072; called by muse, mutect2, varscan2
- CA6 | c.388G>T p.G130W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66262083; called by muse, mutect2, varscan2
- CA9 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV65676428; called by muse, mutect2, varscan2
- CDH2 | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750142878, COSV52280547; called by muse, mutect2, varscan2
- CLPX | c.23C>A p.T8N | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.059); catalogued as COSV55646299; called by muse, mutect2, varscan2
- CSMD1 | c.7345G>T p.A2449S (on ENST00000520002; = p.A2448S on NM_033225.6) | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs774707047; called by muse, mutect2, varscan2
- CTC1 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771759195; called by muse, mutect2, varscan2
- DCAF12L2 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63583915; called by muse, mutect2, varscan2
- DNAH7 | c.10942G>A p.D3648N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199928786, COSV56765957; called by muse, mutect2, varscan2
- DYNC1I1 | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.048); catalogued as COSV61454881; called by muse, mutect2, varscan2
- FAM184B | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs376312038; called by muse, mutect2
- FHOD3 | c.731G>A p.W244* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | catalogued as rs755728970; called by muse, mutect2, varscan2
- FRAS1 | c.4589C>T p.T1530M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757251336, COSV53607772; called by muse, mutect2, varscan2
- FTSJ1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1135401942, COSV50025841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCN1 | c.5678G>A p.R1893H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs905321849, COSV56104032, COSV99039219; called by muse, mutect2, varscan2
- GLIPR1 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs139100030, COSV56991313; called by muse, mutect2, varscan2
- GPR132 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.402); catalogued as COSV61678314; called by muse, mutect2, varscan2
- GREB1 | c.3120G>A p.P1040= | Splice Region (SNP) | VAF 17/89 reads (19%) | catalogued as rs762653939; called by muse, mutect2, varscan2
- HIRA | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs968445888, COSV54278759; called by muse, mutect2, varscan2
- HRNR | c.5836T>C p.S1946P | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV100913537; called by muse, mutect2
- IQGAP3 | c.3976+1G>A p.X1326_splice | Splice Site (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100752166; called by muse, mutect2, varscan2
- KDR | c.2498G>A p.R833Q | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749143449, COSV55771196; called by muse, mutect2, varscan2
- KIF5B | c.2494A>G p.I832V | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV56653893; called by muse, mutect2, varscan2
- KRT38 | c.1364G>T p.R455L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as COSV55846812, COSV55847380; called by muse, mutect2, varscan2
- LRRC32 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs138705487; called by muse, mutect2, varscan2
- LYST | c.3955C>A p.L1319I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as rs1558263999, COSV67703634; called by muse, mutect2, varscan2
- MCUB | c.298C>G p.L100V | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.609); catalogued as rs771513878; called by muse, mutect2, varscan2
- MMRN1 | c.2615C>T p.T872M | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs774204805, COSV53333894, COSV53336592; called by muse, mutect2, varscan2
- MPP6 | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99757389; called by muse, mutect2, varscan2
- MUC5B | c.11657C>T p.T3886M | Missense Mutation (SNP) | VAF 37/310 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs375178891; called by muse, mutect2, varscan2
- MYBPHL | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs779216234, COSV100848906; called by muse, mutect2, varscan2
- MYH15 | c.3623A>C p.H1208P | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1287455788, COSV99843392; called by muse, mutect2
- NIM1K | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770268418, COSV58139511; called by muse, mutect2, varscan2
- OR4D5 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58309425; called by muse, mutect2, varscan2
- OR6F1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs376953062, COSV57469358; called by muse, mutect2, varscan2
- OSGEPL1 | c.886del p.H296Ifs*3 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as COSV51463789; called by mutect2, pindel, varscan2
- OTUD4 | c.218G>A p.R73Q (on ENST00000447906 / NM_001366057.1; = p.R8Q on NM_017493.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs1248582271; called by muse, mutect2, varscan2
- PCDH11X | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 72/418 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100012128, COSV53459295; called by mutect2, varscan2
- PLCG2 | c.2356G>A p.D786N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63878199; called by muse, mutect2, varscan2
- PLEKHO1 | c.674C>A p.A225E | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV50310564; called by muse, mutect2, varscan2
- PLXNB3 | c.2719C>T p.R907W | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs782733468, COSV100737200; called by muse, mutect2, varscan2
- PM20D1 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs199717760, COSV65648532; called by muse, mutect2
- PNMA6A | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.139); catalogued as COSV70278269; called by mutect2, varscan2
- PSMC2 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs771939160, COSV99485081; called by muse, mutect2, varscan2
- PTCH1 | c.2578G>T p.D860Y | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59461117, COSV59491348; called by muse, mutect2, varscan2
- RNF20 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753765875, COSV66660801; called by muse, mutect2, varscan2
- RPGR | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs139594653, COSV100139418; called by muse, mutect2, varscan2
- RPTOR | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as COSV60806220; called by muse, mutect2, varscan2
- SCAF4 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs149907934; called by muse, mutect2, varscan2
- SEMA3G | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1297326681; called by muse, mutect2, varscan2
- SLC2A11 | c.971C>T p.T324M (on ENST00000345044 / NM_001024938.4; = p.T331M on NM_030807.5) | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as rs540314158; called by muse, mutect2, varscan2
- SLC45A1 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.014); catalogued as rs372023133; called by muse, mutect2, varscan2
- TAS1R2 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs138972387, COSV64743801; called by muse, mutect2, varscan2
- TESK1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264766742, COSV52410694; called by mutect2, varscan2
- TET1 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs754324920; called by muse, mutect2, varscan2
- TIMELESS | c.3362C>G p.S1121C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.361); catalogued as COSV57511727; called by muse, mutect2, varscan2
- TINAG | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.114); catalogued as rs75755871; called by muse, mutect2, varscan2
- TMEM26 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs576822697, COSV53261659, COSV99515694; called by muse, mutect2, varscan2
- TMEM63B | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52477082; called by muse, mutect2, varscan2
- TRIO | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 73/346 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs753710560, COSV60081090; called by muse, mutect2, varscan2
- TTN | c.23962C>T p.R7988* (on ENST00000591111; = p.R7061* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as rs760266983, COSV59947018; called by muse, mutect2, varscan2
- UNC80 | c.3042C>T p.H1014= | Splice Region (SNP) | VAF 9/40 reads (23%) | catalogued as rs572393115, COSV99779565; called by muse, mutect2, varscan2
- VCP | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as COSV62719513; called by mutect2, varscan2
- WNT9B | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200104547, COSV51518710; called by muse, mutect2, varscan2
- XIRP2 | c.7451T>G p.V2484G (on ENST00000628543; = p.V2659G on NM_152381.6) | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54688577, COSV54710565; called by muse, mutect2, varscan2
- ZBED1 | c.1044C>G p.S348R | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV58131493, COSV58138268; called by muse, mutect2, varscan2
- ZMAT1 | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 21/96 reads (22%) | catalogued as COSV65659900; called by muse, mutect2, varscan2
- ZNF208 | c.2774C>G p.A925G | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV68111729; called by muse, mutect2, varscan2
- ZNF536 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.361); catalogued as COSV100835935; called by muse, mutect2, varscan2
- ZNF574 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs376193704; called by muse, mutect2, varscan2
- ZNF804B | c.3878C>A p.P1293H | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775694882; called by muse, mutect2, varscan2
- ZNRF3 | c.1300G>A p.G434S (on ENST00000544604 / NM_001206998.2; = p.G334S on NM_032173.3) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs779844636, COSV60432870; called by muse, mutect2, varscan2
- ADAMTS16 | c.3555G>T p.K1185N | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ADCK5 | c.29T>C p.F10S | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- ADCY8 | c.2993C>A p.T998N | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- ADGRV1 | c.4220C>A p.A1407D | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- AFF4 | c.1330_1331del p.S444* | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by pindel, varscan2
- ANKRD35 | c.175C>A p.H59N | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APC | c.3989_3990del p.P1330Qfs*11 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | called by mutect2, pindel, varscan2
- ATL3 | c.1201A>G p.T401A | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- BMPR2 | c.1748dup p.N583Kfs*6 | Frame Shift Ins (INS) | VAF 12/74 reads (16%) | called by mutect2, varscan2
- CACNA1C | c.3520dup p.E1174Gfs*8 | Frame Shift Ins (INS) | VAF 23/155 reads (15%) | called by mutect2, pindel, varscan2
- CDHR2 | c.3652C>A p.R1218= | Splice Region (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- CLMP | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DRP2 | c.2408T>G p.L803R | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- EPSTI1 | c.825A>C p.K275N (on ENST00000398762 / NM_001330543.2; = p.K264N on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- ESYT1 | c.1757G>A p.R586K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); called by mutect2, varscan2
- FAM135B | c.2756C>A p.S919Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAM160A1 | c.1190T>G p.L397* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- FIBCD1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRB3 | c.1093G>T p.G365* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- GPATCH8 | c.120+2dup | Splice Region (INS) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- GRIA1 | c.2444G>T p.G815V | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HIBADH | c.722C>G p.A241G | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- HNRNPAB | c.976C>T p.Q326* (on ENST00000504898; = p.Q279* on NM_004499.4) | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- HOXD4 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSD17B11 | c.9del p.L4Ffs*11 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- IFT80 | c.1930G>C p.D644H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2
- IRS1 | c.1820A>G p.H607R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ITGAM | c.2276_2277del p.R759Tfs*9 (on ENST00000648685 / NM_001145808.2; = p.R758Tfs*9 on NM_000632.4) | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by pindel, varscan2
- KDM5C | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KIAA1210 | c.5113G>C p.A1705P | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- KIZ | c.300G>T p.K100N | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- METTL21C | c.341C>A p.A114E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); called by muse, mutect2
- MKX | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NAA25 | c.32A>T p.N11I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- NUP214 | c.3442G>A p.A1148T | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR4K2 | c.248C>A p.T83K | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR51G1 | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR7A10 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- PAPPA2 | c.2478G>T p.M826I | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPPA2 | c.4064T>C p.V1355A | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PARP15 | c.595_598del p.F199Hfs*7 | Frame Shift Del (DEL) | VAF 15/105 reads (14%) | called by mutect2, pindel, varscan2
- PLEC | c.8495G>T p.R2832L (on ENST00000322810 / NM_201380.4; = p.R2722L on NM_000445.5) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PLEKHG3 | c.2707G>A p.D903N (on ENST00000394691; = p.D959N on NM_001308147.2) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PROM1 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- RSAD2 | c.785_820del p.A262_D273del | In Frame Del (DEL) | VAF 24/182 reads (13%) | called by mutect2, pindel
- RTL8C | c.25A>T p.K9* | Nonsense Mutation (SNP) | VAF 28/156 reads (18%) | called by mutect2, varscan2
- SI | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- SLC24A4 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.048); called by muse, mutect2
- SOX9 | c.709_710del p.P237Tfs*14 | Frame Shift Del (DEL) | VAF 28/109 reads (26%) | called by mutect2, pindel, varscan2
- SPO11 | c.392C>A p.A131E | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- SRCAP | c.6845G>A p.G2282E | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- SRCIN1 | c.590G>A p.R197Q (on ENST00000621492; = p.R163Q on NM_025248.3) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TCTN1 | c.382T>C p.S128P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- TGFBR2 | c.1564_1567dup p.H523Rfs*19 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- TTN | c.4909G>A p.G1637S (on ENST00000591111; = p.G1591S on NM_003319.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF14 | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF449 | c.1053C>A p.H351Q | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ACACB | c.6189C>T p.S2063= | Silent (SNP) | VAF 33/207 reads (16%) | catalogued as rs773461289, COSV58144480; called by muse, mutect2, varscan2
- ADAMTS12 | c.4278G>A p.A1426= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs149971505; called by muse, mutect2, varscan2
- APC2 | c.1482C>T p.I494= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as rs368821154, COSV52021610; called by muse, mutect2, varscan2
- CACNA2D3 | c.2682C>A p.S894= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as COSV55577560, COSV55578584; called by muse, mutect2, varscan2
- CAVIN2 | c.1197C>T p.Y399= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs756905753, COSV58426213; called by muse, mutect2, varscan2
- CCER1 | c.900G>A p.A300= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs772840605, COSV62646755; called by muse, mutect2, varscan2
- CDK12 | c.1647C>T p.P549= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs1567686787; called by muse, mutect2, varscan2
- CHRNA4 | c.729G>A p.P243= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as rs121912253, COSV64721599; ClinVar: uncertain significance / likely benign / not provided; called by muse, mutect2, varscan2
- CHRNB2 | c.879C>T p.D293= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV100872621; called by mutect2, varscan2
- CLN8 | c.78G>A p.T26= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as rs933753788, COSV58671408; called by muse, mutect2, varscan2
- CNOT4 | c.876G>A p.Q292= (on ENST00000315544 / NM_001190848.1; = p.Q289= on NM_013316.4) | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV59657936; called by muse, mutect2
- COL8A1 | c.528G>C p.G176= | Silent (SNP) | VAF 37/242 reads (15%) | catalogued as COSV53741199; called by muse, mutect2, varscan2
- CPSF6 | c.1056G>A p.P352= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs765622604, COSV57017166; called by muse, mutect2, varscan2
- CRIM1 | c.2709C>T p.P903= | Silent (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- CXorf65 | c.138G>A p.T46= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as rs764170798; called by muse, mutect2
- FAM83B | c.1278G>A p.A426= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs771043633; called by muse, mutect2, varscan2
- FRMPD3 | c.4329G>A p.S1443= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs759239236, COSV52196546; called by muse, mutect2, varscan2
- GAL3ST2 | c.84C>T p.A28= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs376854402; called by muse, mutect2, varscan2
- GALNT17 | c.1284C>A p.I428= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as COSV61176973; called by muse, mutect2, varscan2
- GAS2 | c.405T>G p.G135= | Silent (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- GPNMB | c.654G>A p.R218= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as rs1043106907, COSV51698509; called by muse, mutect2, varscan2
- GSN | c.381G>A p.A127= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs761824852, COSV58000888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H1-7 | c.255C>T p.N85= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV58602894; called by muse, mutect2, varscan2
- HACL1 | c.51T>G p.A17= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- HAGHL | c.739C>T p.L247= (on ENST00000341413; = p.T209I on NM_032304.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV52403318; called by muse, mutect2, varscan2
- ITIH1 | c.82C>T p.L28= | Silent (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- KRT72 | c.891C>T p.A297= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as rs367576767; called by muse, mutect2, varscan2
- LRRC43 | c.813C>T p.I271= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as rs760404558, COSV60292927; called by muse, mutect2, varscan2
- MEFV | c.867G>A p.A289= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs984945497, COSV99560879, COSV99561420; called by muse, mutect2, varscan2
- MUC4 | c.7440T>G p.P2480= | Silent (SNP) | VAF 37/210 reads (18%) | catalogued as rs779643242, COSV100640665; called by muse, varscan2
- MVP | c.1827G>A p.S609= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs113018337, COSV100651601; called by muse, mutect2, varscan2
- NR4A1 | c.174C>T p.D58= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs774267356, COSV54485973; called by muse, mutect2, varscan2
- OR10A6 | c.459T>C p.F153= | Silent (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- PCDH9 | c.174C>G p.T58= | Silent (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- PEX5 | c.1893C>T p.L631= (on ENST00000420616; = p.L623= on NM_000319.5) | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs143610074; called by muse, mutect2, varscan2
- PHF1 | c.885C>T p.D295= | Silent (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- RAI1 | c.1113C>T p.P371= | Silent (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- RBMXL3 | c.3063G>A p.P1021= | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as rs375818310, COSV57745079; called by muse, mutect2, varscan2
- RSPO4 | c.316C>A p.R106= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- RYR3 | c.12510C>T p.N4170= (on ENST00000389232; = p.N4171= on NM_001036.6) | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as rs770461745, COSV101213634; called by muse, mutect2, varscan2
- SEMA6A | c.2460C>T p.I820= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs575055741; called by muse, mutect2, varscan2
- SEPTIN14 | c.951C>A p.G317= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs1337387197; called by muse, mutect2, varscan2
- SERPINB13 | c.1155C>T p.F385= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs777570529, COSV54028726; called by muse, mutect2, varscan2
- SLC41A1 | c.168C>T p.N56= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs776970789, COSV65651338; called by muse, mutect2, varscan2
- SPC24 | c.246G>A p.Q82= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs1300930147; called by muse, mutect2, varscan2
- SYNM | c.1254C>T p.A418= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs782527382, COSV60374115; called by muse, mutect2, varscan2
- TPO | c.1443G>A p.V481= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs377537666; called by muse, mutect2, varscan2
- TRDMT1 | c.288G>A p.T96= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs138454921, COSV58318990; called by mutect2, varscan2
- TRIM43 | c.252A>G p.Q84= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs772296746; called by muse, mutect2, varscan2
- WDR27 | c.1065C>T p.S355= | Silent (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- ZNF423 | c.1290G>A p.L430= (on ENST00000563137 / NM_001379286.1; = p.L422= on NM_015069.4) | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs1449060937; called by muse, mutect2, varscan2
- ZNF846 | c.1335T>G p.T445= | Silent (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- ZXDC | c.729C>T p.G243= | Silent (SNP) | VAF 48/226 reads (21%) | catalogued as rs773995576, COSV60448449; called by muse, mutect2, varscan2
- CACNA2D1 | c.1931-701dup | Intron (INS) | VAF 32/181 reads (18%) | catalogued as rs1347383693; called by mutect2, pindel, varscan2
- CCHCR1 | c.-51-361C>A | Intron (SNP) | VAF 12/90 reads (13%) | called by mutect2, varscan2
- CLPS | chr6:35793520 T>C | 3'Flank (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- EID1 | c.*157G>A | 3'UTR (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100194678; called by muse, mutect2, varscan2
- FAM133A | c.*270del | 3'UTR (DEL) | VAF 38/180 reads (21%) | catalogued as rs769947198; called by mutect2, varscan2
- GLOD4 | chr17:782653 T>C | 5'Flank (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- ILF3 | c.2059+857G>A | Intron (SNP) | VAF 10/69 reads (14%) | catalogued as rs375693738; called by muse, mutect2, varscan2
- MEX3D | c.*184G>A | 3'UTR (SNP) | VAF 16/87 reads (18%) | catalogued as rs1465599387; called by muse, mutect2, varscan2
- MGAT3 | c.*621A>T | 3'UTR (SNP) | VAF 18/90 reads (20%) | catalogued as COSV100361914; called by muse, mutect2, varscan2
- MIR421 | chrX:74218546 T>C | 5'Flank (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- NAP1L2 | c.-229G>A | 5'UTR (SNP) | VAF 23/120 reads (19%) | catalogued as COSV100999212; called by muse, mutect2, varscan2
- OR52A4P | chr11:5121055 C>T | 3'Flank (SNP) | VAF 21/112 reads (19%) | catalogued as rs369472582; called by muse, mutect2, varscan2
- RPP25 | chr15:74957270 G>A | 5'Flank (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100446221; called by muse, mutect2, varscan2
- SOX11 | c.*1677G>A | 3'UTR (SNP) | VAF 9/62 reads (15%) | catalogued as rs1331190150, COSV100431172; called by muse, mutect2, varscan2
- SPOUT1 | c.508+26dup | Intron (INS) | VAF 10/48 reads (21%) | catalogued as rs763016788; called by mutect2, varscan2
- ZNF510 | c.-12C>T | 5'UTR (SNP) | VAF 9/87 reads (10%) | catalogued as COSV99793883; called by muse, mutect2, varscan2
